Somatic mutation profile of tumor specimen C3L-05816-54 (aliquot CPT0341500002) from CPTAC case C3L-05816, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 73.3 years (26,764 days).
Specimen C3L-05816-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f46a0bc-75e3-4330-ac11-b28b6a1f5d25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05816-51 (Buccal Cell Normal), aliquot CPT0341470002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ea83494-9850-4332-ab57-4c94082b3799

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, 3'UTR 2, Intron 1, Frame Shift Ins 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 81/244 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 16/79 reads (20%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FAM227A | c.1224G>A p.S408= | Splice Region (SNP) | VAF 68/124 reads (55%) | catalogued as rs1011880132; called by muse, mutect2, varscan2
- FMO3 | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs371057073; called by muse, mutect2, varscan2
- KCNB2 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV73049920, COSV73053662; called by muse, mutect2, varscan2
- MROH2B | c.2133T>A p.H711Q | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.094); catalogued as rs899698469; called by muse, mutect2, varscan2
- POTEC | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 106/312 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as rs544384663; called by muse, mutect2, varscan2
- STN1 | c.487C>G p.Q163E | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56544552, COSV56545595; called by muse, mutect2, varscan2
- VWA5B1 | c.2704G>A p.V902M | Missense Mutation (SNP) | VAF 85/192 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); catalogued as rs375822512; called by muse, mutect2, varscan2
- DOP1B | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- DSCAM | c.1501G>A p.V501I | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SCD | c.805C>T p.H269Y | Missense Mutation (SNP) | VAF 166/358 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- GABRR2 | c.906G>C p.L302= | Silent (SNP) | VAF 67/138 reads (49%) | called by muse, mutect2, varscan2
- HGH1 | c.621T>C p.L207= | Silent (SNP) | VAF 14/338 reads (4%) | called by muse, mutect2
- SPATA31D1 | c.46C>T p.L16= | Silent (SNP) | VAF 123/277 reads (44%) | called by muse, mutect2, varscan2
- POU2F3 | chr11:120236660 del A | 5'Flank (DEL) | VAF 32/94 reads (34%) | called by mutect2, pindel, varscan2
- SHROOM4 | c.*1346G>A | 3'UTR (SNP) | VAF 35/40 reads (88%) | called by muse, mutect2, varscan2
- SLC19A3 | c.150+1144G>A | Intron (SNP) | VAF 8/156 reads (5%) | catalogued as rs978167145, COSV99295686; called by muse, mutect2
- SRP19 | c.*930C>T | 3'UTR (SNP) | VAF 142/478 reads (30%) | catalogued as rs756841975; called by muse, mutect2, varscan2
